Somatic mutation profile of tumor specimen MBCProject_3717_T2_WES (aliquot MBCProject_3717_T2_WES_1) from CMI case MBCProject_3717, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Ductal carcinoma in situ, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.3 years (16,182 days).
Specimen MBCProject_3717_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93e1ddee-ed99-4060-9afb-4b6851ed75fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3717_SALIVA (Saliva), aliquot MBCProject_3717_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dab2ab34-a96e-4024-9991-6a215678295e

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 5, Nonsense Mutation 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV52827694; called by muse, mutect2, varscan2
- GPI | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1232259568; called by muse, mutect2
- PDS5A | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV57826067; called by muse, mutect2, varscan2
- USP26 | c.2562G>A p.W854* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100896499; called by muse, mutect2
- MFSD8 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- PPP1R12A | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SUDS3 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNAAF4 | c.369G>A p.R123= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- FBXO33 | c.333C>T p.L111= | Silent (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- ITCH | c.1002G>A p.Q334= (on ENST00000262650 / NM_001257137.3; = p.Q293= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- RNF213 | c.10389C>T p.I3463= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- ST7 | c.105C>T p.V35= | Silent (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- TRMT12 | c.126C>G p.L42= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1306963768, COSV60777691; called by muse, varscan2
- CDK17 | c.1322+27G>A | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- HSPA9 | c.-16C>T | 5'UTR (SNP) | VAF 3/14 reads (21%) | catalogued as rs770432313; called by muse, mutect2
